Surgical pathology report (de-identified scan), TCGA case TCGA-HU-A4G6, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site National Cancer Center Korea, specimen TCGA-HU-A4G6-01A (Primary Tumor).

[page 1 of 2]
Stomach, total gastrectomy:

Early gastric carcinoma

(Muc2(-)/Muc5AC(-)/Muc6(-)/CD10(-)/cERB2(+++), Null type)

1. Location : upper third, Center at cardia, lesser curvature
2. Gross type : EGC type 0-1+IIa
3. Histologic type : papillary adenocarcinoma (60%)
>> poorly differentiated carcinoma, solid type (40%)

<Addendum>

Final diagnosis: stomach adenocarcinoma, papillary intestinal.

4. Histologic type by Lauren : intestinal
5. Growth pattern: expanding growth pattern
6. Size : 2.9x2.5cm
7. Depth of invasion : invades submucosa (sm3) (pT1b)
[sm invasion depth/sm depth: 2000um/2375um]
8. Resection margin: free from carcinoma
safety margin: distal 15.5cm, proximal 0.6cm
9. Lymph node metastasis : no metastasis in 53 regional lymph nodes (pN0)
(lesser curvature 0/27 , greater curvature 0/26)
10. Lymphatic invasion : not identified
11. Venous invasion : not identified
12. Perineural invasion : not identified
13. Associated findings : foveolar hyperplasia and pit dysplasia
- Specimen labeled as Anvil ring: No tumor.
- Small intestine, jejunum, biopsy: No tumor.
- Lymph node, middle colic artery, biopsy: No tumor (0/2).
- Lymph node, middle colic vein, biopsy: No tumor (0/1).
- Lymph node, biopsy: No tumor (0/0).
- Lymph node, 12a, biopsy: No tumor (0/0).

Immunohistochemistry : CD10, MUC2, MUC5ac, MUC6, C-erb B2

ICD-O-3

adenocarcinoma, papillary, NOS 8260/3

Site: Stomach, cardia, NOS C16.0

hw
9/27/12

QUALIFIED / DISQUALIFIED	QUALIFIED	

hw 9/24/12

[page 2 of 2]
TCGA Pathologic Diagnosis Discrepancy Form

Instructions: The TCGA Pathologic Diagnosis Discrepancy Form should be completed when the pathologic diagnosis submitted on the initial pathology report for a case submitted for TCGA is inconsistent with the diagnosis provided on the Case Quality Control Form completed for the submitted case.

Tissue Source Site (TSS): Stomach adenocarcinoma

Completed By

Discrepancy Information

#	Data Element	Entry Alternatives	Working Instructions
1	Pathologic Diagnosis Provided on Initial Pathology Report	Stomach Adenocarcinoma, Papillary Type 60% & Solid Type 40% - Intestinal	Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.
2	Histologic features of the sample provided for TCGA, as reflected on the CQCF	Stomach Intestinal Adenocarcinoma, Papillary Type	Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.

Discrepancy between Pathology Report and Case Quality Control Form

3	Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form.	Original pathology report (for the whole resected specimen) mentioned 40% of solid type adenocarcinoma, which was not found in TCGA top slide.	Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.
4	Name of TSS Reviewing Pathologist or Biorepository Director		Provide the name of the pathologist who reviewed this case for TCGA

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled.

TSS Reviewing Pathologist or Biorepository Director

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled. The Attending Pathologist or the Department Chairman has been informed or is aware of the above discrepancy in diagnoses.

Principal Investigator Signature

Date

Source: NCI Genomic Data Commons file 72520aa9-6452-4756-b472-dc0fe46ff699 (TCGA-HU-A4G6.40D0F685-74EA-47D5-AD9D-A9C5806D5651.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).